Somatic mutation profile of tumor specimen TCGA-S9-A6WO-01A (aliquot TCGA-S9-A6WO-01A-21D-A34A-08) from TCGA case TCGA-S9-A6WO, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 29.9 years (10,933 days).
Specimen TCGA-S9-A6WO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9328aed-046d-4280-b535-a60d074daaa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6WO-10A (Blood Derived Normal), aliquot TCGA-S9-A6WO-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cf1d8c4-ebe0-4578-b585-eb93c4619a71

The open-access MAF lists 29 somatic variants for this specimen: 26 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 19, Nonsense Mutation 4, Silent 3, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 55/125 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 84/100 reads (84%) | hotspot (GDC flag); catalogued as COSV52734595, COSV53139118; called by muse, mutect2, varscan2
- ANKRD30A | c.2021A>G p.E674G (on ENST00000611781; = p.E618G on NM_052997.2) | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.775); catalogued as COSV100653004; called by muse, mutect2, varscan2
- ATRX | c.789G>A p.W263* | Nonsense Mutation (SNP) | VAF 18/223 reads (8%) | catalogued as COSV64878305; called by muse, mutect2
- C1orf87 | c.504T>G p.S168R | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1038678940, COSV100966941; called by muse, mutect2, varscan2
- CASP8 | c.352A>G p.R118G (on ENST00000432109 / NM_033355.3; = p.R150G on NM_001228.4) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV99964732; called by muse, mutect2, varscan2
- CDH19 | c.1655T>C p.I552T | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100050967; called by muse, mutect2, varscan2
- CTNNA2 | c.2399A>G p.Q800R | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100559557; called by muse, mutect2
- DYSF | c.3036G>A p.W1012* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99244699; called by muse, mutect2, varscan2
- GCNT3 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142393489, COSV68532653; called by muse, mutect2
- HSPA2 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV55968812; called by muse, mutect2
- IL16 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100267084; called by muse, mutect2, varscan2
- LEF1 | c.1165+2T>C p.X389_splice | Splice Site (SNP) | VAF 22/94 reads (23%) | catalogued as COSV99489295; called by muse, mutect2, varscan2
- OR5J2 | c.736A>G p.T246A | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV100398884; called by muse, mutect2, varscan2
- PAXIP1 | c.857A>G p.E286G | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs1380928465, COSV101249404; called by muse, mutect2
- PDP2 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV100305838; called by muse, mutect2, varscan2
- PRG4 | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs150567824; called by muse, mutect2, varscan2
- RFX7 | c.634C>T p.R212W (on ENST00000559447 / NM_001368074.1; = p.R309W on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753217039, COSV100428099; called by muse, mutect2, varscan2
- SEPHS1 | c.31A>G p.S11G | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100525683; called by muse, mutect2
- SH2B2 | c.1577G>A p.W526* | Nonsense Mutation (SNP) | VAF 13/185 reads (7%) | catalogued as COSV100159237; called by muse, mutect2
- SLC9C2 | c.590T>C p.I197T | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100876585, COSV62944014, COSV62945048; called by muse, mutect2, varscan2
- SLCO4C1 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs777363737, COSV100194562; called by muse, mutect2, varscan2
- TACC2 | c.5041C>A p.P1681T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100551667; called by mutect2, varscan2
- ZMAT1 | c.1553A>G p.Y518C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as rs1249098081, COSV100858693; called by muse, mutect2
- ATRX | c.2069_2070del p.K690Tfs*10 | Frame Shift Del (DEL) | VAF 110/235 reads (47%) | called by mutect2, pindel, varscan2
- DACH2 | c.488+2_488+3del p.X163_splice | Splice Site (DEL) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- CARD11 | c.654G>A p.A218= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs113957419, COSV100712213, COSV62716264; called by muse, mutect2, varscan2
- MYH7 | c.4365G>A p.E1455= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100805743; called by muse, mutect2
- OR5M3 | c.606C>G p.G202= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as COSV100392322, COSV56568447; called by muse, mutect2, varscan2
